Somatic mutation profile of tumor specimen BA2474D (aliquot aq-BA2474D) from BEATAML1.0 case 2029, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.4 years (16,941 days).
Specimen BA2474D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ceda3022-3e5c-45f4-87c0-9036526fbc56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2368D (Solid Tissue Normal), aliquot aq-BA2368D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a745f6b-9d4c-459a-a4b8-92795cc66381

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRM4 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as rs201918690, COSV65216725; called by muse, mutect2, varscan2
- HSCB | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
